Gene-level copy-number profile of specimen HCM-BROD-0209-C71-85A from HCMI case HCM-BROD-0209-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 41.8 years (15,280 days).
Specimen HCM-BROD-0209-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e162b99f-d069-4afb-8948-3ec2b8d93627.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0209-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/94fb0fa5-0259-4410-8234-6019c6fe6912

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 8,228; copy number 3: 7,678; copy number 4: 36,630; copy number 5: 1,332; copy number 6: 4,128; copy number 7: 632; copy number 8: 48; copy number 9: 18; copy number 14: 8; copy number 15: 2; copy number 16: 9; copy number 18: 24; copy number 19: 30; copy number 20: 20; copy number 21: 28; copy number 22: 2; copy number 23: 11; copy number 24: 27; copy number 25: 11; copy number 29: 1; copy number 31: 1; copy number 32: 18; copy number 35: 23.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 233 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–71,585, 3 genes, copy number 9: OR4G4P, OR4G11P, OR4F5.
- chr1:137,682–359,681, 10 genes, copy number 14–15 (within-gene range 4–15): AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2.
- chr7:30,752,137–30,993,254, 6 genes, copy number 9 (within-gene range 7–9): INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR.
- chr7:54,621,025–55,211,628, 7 genes, copy number 9: RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr7:141,500,079–141,551,304, 2 genes, copy number 9 (within-gene range 6–9): AC073878.1, AC073878.2.
- chr8:13,044,350–13,044,456, 1 gene, copy number 22: RNU6-842P.
- chr8:28,494,205–29,263,124, 17 genes, copy number 20: FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23.
- chr8:53,388,701–53,390,872, 1 gene, copy number 20: AC131902.1.
- chr8:53,394,215–53,394,795, 1 gene, copy number 20: AC131902.2.
- chr8:75,376,709–75,566,834, 2 genes, copy number 23: PKMP4, HNF4G.
- chr8:87,867,601–91,040,872, 31 genes, copy number 18–25: AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1.
- chr8:94,249,253–94,262,350, 1 gene, copy number 23: GEM.
- chr8:94,553,668–97,358,478, 53 genes, copy number 21–24: AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P, SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H.
- chr8:100,572,889–101,393,255, 30 genes, copy number 19: SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845.
- chr8:114,791,653–114,791,929, 1 gene, copy number 31: CARS1P2.
- chr8:126,174,186–129,786,624, 42 genes, copy number 22–35: RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC.
- chr8:132,024,216–132,848,807, 11 genes, copy number 18: OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1.
- chr8:135,234,131–135,742,495, 5 genes, copy number 18–29: LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr8:141,207,166–141,367,286, 9 genes, copy number 16: SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
